TCGA case TCGA-46-3769 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: St. Joseph's Medical Center (MD). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d38dbe20-bd5a-45d5-8db3-d5f777b454b6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,941 days); Year of diagnosis: 2009; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 135 days; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 77 days; Treatment dose: 63 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (2 entries)
- Days to follow up: 121 days; Disease response: Tumor Free.
- Days to follow up: 135 days; Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-46-3769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-46-3769-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 10.
  Slide TCGA-46-3769-01A-01-BS1: Section location: Bottom; Percent tumor cells: 87; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 10.
- Sample TCGA-46-3769-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-46-3769-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: Yes; Eml4 alk translocation status: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Cisplatin/Etoposide.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 135 days; disease-specific survival: no event (censored), 135 days; disease-free interval: no event (censored), 135 days; progression-free interval: no event (censored), 135 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-46-3769-01A-01D-0978-01): tumor purity 0.47, ploidy 3.65, whole-genome doublings 2.
